CGCI case BLGSP-71-19-00127 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/17d5247e-0813-4c73-bbca-17044494716e

Demographics
Sex at birth: male; Race: black or african american; Age at index: 20 years; Vital status: Dead; Days to death: 231 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt-like lymphoma: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Classification of tumor: primary; Age at diagnosis: 20.2 years (7,385 days); Year of diagnosis: 2006; Method of diagnosis: Bone Marrow Aspirate; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Days to last follow up: 230 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Bone marrow; Sites of involvement: Bone marrow / Cerebrospinal fluid / Liver / Pleura / Peripheral nervous system.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Axillary.
   Pathology details: Lymph node involved site: Inguinal.
   Pathology details: Lymph node involved site: Splenic.
   Treatment given: Treatment intent type: Neoadjuvant; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 230 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- BCL6: Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD10: Negative; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD20: Positive.
- CD3 (IHC): Negative.
- CD3: Negative.
- CD79A: Positive.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- Ki67: Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Epstein-Barr Virus (ISH): Positive.
- Lactate Dehydrogenase 10360 [Blood test normal range upper: 260].

Other clinical attributes
- Day 0: Comorbidities: HIV/AIDS.
- Day 0: Risk factors: HIV/AIDS.
- Day 0: Weight: 61 kg; Height: 170 cm; BMI: 21.1; Haart treatment indicator: Yes.
- Day 0: Cdc hiv risk factors: Heterosexual Contact.

Biospecimens (3 samples)
- Sample BLGSP-71-19-00127-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-19-00127-04A.1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Sorted Cells; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Days to sample procurement: 157 days; Method of sample procurement: Aspirate; Tissue collection type: Retrospective.
- Sample BLGSP-71-19-00127-16A: Sample type: Mononuclear Cells from Bone Marrow Normal; Tissue type: Normal; Specimen type: Mononuclear Cells from Bone Marrow; Preservation method: Frozen; Days to sample procurement: 157 days; Method of sample procurement: Bone Marrow Aspirate; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: Yes; Tumor status: With tumor; Treatment outcome first course: Progressive Disease; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Haart therapy prior to diagnosis: No; Haart therapy at diagnosis: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), atypical morphology; Extranodal site involvement: 5; Extranodal involvment other: cranial nerve VII; Lymph nodes examined: No; Bone marrow sample histology: Concordant Histology.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 10360; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD79a.
